Somatic mutation profile of tumor specimen MMRF_2181_1_BM_CD138pos (aliquot MMRF_2181_1_BM_CD138pos_T1_KHS5U_L09512) from MMRF case MMRF_2181, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.3 years (29,336 days).
Specimen MMRF_2181_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ca15f87-680b-4b0e-b15f-e208670b1bd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2181_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2181_1_PB_CD3pos_C2_KHS5U_L09511; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1153f85f-aab2-416f-9354-a6d6a29175c2

The open-access MAF lists 68 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 23, Missense Mutation 19, Intron 9, Silent 7, Nonsense Mutation 4, 5'UTR 2, 5'Flank 1, RNA 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO4 | c.1895G>A p.W632* (on ENST00000392977 / NM_001286615.2; = p.W597* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100152761, COSV54601926; called by mutect2, varscan2
- C17orf49 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV66080710; called by muse, mutect2
- CHPT1 | c.365A>G p.N122S | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as rs1387742434; called by muse, mutect2
- FAM184B | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as rs376068083; called by muse, varscan2
- FBXW11 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 11/98 reads (11%) | catalogued as COSV51608202; called by muse, mutect2, varscan2
- IL20RA | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.306); catalogued as rs966447793, COSV57356930; called by muse, mutect2
- LRRTM4 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as COSV101297409; called by muse, mutect2
- PCDHA11 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 16/148 reads (11%) | catalogued as COSV56502825; called by mutect2, varscan2
- POU1F1 | c.610T>C p.Y204H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.994); catalogued as rs1192923871; called by muse, mutect2, varscan2
- PYDC1 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV57250646, COSV57252095; called by muse, mutect2
- TOPBP1 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV53443060; called by muse, mutect2, varscan2
- TRPM4 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.268); catalogued as rs988311676, COSV99419297; called by muse, mutect2, varscan2
- USP11 | c.769A>G p.T257A (on ENST00000218348; = p.T214A on NM_001371072.1) | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.039); catalogued as rs1378498421; called by muse, mutect2
- USP44 | c.1968A>T p.K656N | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.838); catalogued as COSV51565794; called by muse, mutect2
- CEP250 | c.5364G>C p.Q1788H | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- IGLC3 | c.188A>T p.N63I | Missense Mutation (SNP) | VAF 21/33 reads (64%) | PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MAP3K14 | c.212C>G p.S71C | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- OR10T2 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.031); called by muse, mutect2
- RAD23B | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, mutect2
- RNGTT | c.398C>G p.T133S | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- STAG3 | c.3485C>G p.S1162* | Nonsense Mutation (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- SYT17 | c.714C>G p.D238E | Missense Mutation (SNP) | VAF 11/357 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); called by muse, mutect2
- TFR2 | c.2210G>A p.G737E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- YPEL3 | c.270+4A>C | Splice Region (SNP) | VAF 44/94 reads (47%) | called by muse, varscan2
- CD300A | c.693C>T p.Y231= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs367981449; called by muse, mutect2, varscan2
- ELMOD1 | c.462G>A p.R154= | Silent (SNP) | VAF 73/175 reads (42%) | catalogued as COSV99760549; called by muse, mutect2, varscan2
- LOXHD1 | c.699G>A p.L233= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- PCNT | c.6321G>A p.E2107= | Silent (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2
- SCIN | c.1716C>T p.V572= (on ENST00000297029 / NM_001112706.3; = p.V325= on NM_033128.3) | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as rs1480303949; called by muse, mutect2, varscan2
- TES | c.1134C>T p.N378= | Silent (SNP) | VAF 11/182 reads (6%) | called by muse, mutect2
- TMPRSS2 | c.435G>A p.E145= | Silent (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- ALG11 | c.*4495C>T | 3'UTR (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2
- AMFR | c.*69T>G | 3'UTR (SNP) | VAF 13/282 reads (5%) | called by muse, mutect2
- ATRX | c.*2209_*2211del | 3'UTR (DEL) | VAF 8/58 reads (14%) | called by pindel, varscan2
- C18orf54 | c.*2537C>T | 3'UTR (SNP) | VAF 6/144 reads (4%) | catalogued as rs886991141; called by muse, mutect2
- CA1 | c.*2G>A | 3'UTR (SNP) | VAF 12/321 reads (4%) | called by muse, mutect2
- CAB39L | c.*1018C>T | 3'UTR (SNP) | VAF 10/100 reads (10%) | called by mutect2, varscan2
- CACNG7 | chr19:53943782 G>A | 3'Flank (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- CAPRIN2 | c.-530C>T | 5'UTR (SNP) | VAF 17/243 reads (7%) | called by muse, mutect2
- CDH20 | c.*175C>T | 3'UTR (SNP) | VAF 4/31 reads (13%) | catalogued as rs1490317225; called by muse, mutect2
- CUBN | c.*677G>A | 3'UTR (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- DEPP1 | c.*1088T>A | 3'UTR (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- DISC1 | c.*991G>A | 3'UTR (SNP) | VAF 13/324 reads (4%) | called by muse, mutect2
- ERGIC1 | c.375+1327G>A | Intron (SNP) | VAF 19/155 reads (12%) | called by muse, mutect2, varscan2
- FAM111A | c.*91C>T | 3'UTR (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
- FBN1 | c.164+1783C>T | Intron (SNP) | VAF 5/48 reads (10%) | called by muse, varscan2
- FGFR2 | c.2301+1541A>T | Intron (SNP) | VAF 24/318 reads (8%) | called by muse, mutect2
- GPM6A | c.*555C>T | 3'UTR (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2
- HAUS6 | c.2806+115C>T | Intron (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- IL6ST | c.*2087C>T | 3'UTR (SNP) | VAF 45/92 reads (49%) | called by muse, mutect2, varscan2
- ITPK1 | c.120+10253T>C | Intron (SNP) | VAF 4/33 reads (12%) | catalogued as rs750992034, COSV50895087; called by muse, varscan2
- LAMB1 | c.2459-38G>C | Intron (SNP) | VAF 31/381 reads (8%) | catalogued as rs1562989649; called by muse, mutect2
- MANEA | c.*1163T>G | 3'UTR (SNP) | VAF 9/45 reads (20%) | called by muse, varscan2
- MATR3 | c.*1848G>A | 3'UTR (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- MFSD4A | c.*253G>A | 3'UTR (SNP) | VAF 8/218 reads (4%) | called by muse, mutect2
- MIR9-2 | chr5:88667428 C>T | 5'Flank (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- NACA4P | n.997C>G | RNA (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- PKP3 | c.-36G>A | 5'UTR (SNP) | VAF 6/62 reads (10%) | catalogued as rs966242838; called by mutect2, varscan2
- PLOD2 | c.1128-408A>T | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- PRKAA1 | c.*51C>T | 3'UTR (SNP) | VAF 8/131 reads (6%) | called by muse, mutect2
- PTCD1 | c.*968G>A | 3'UTR (SNP) | VAF 9/121 reads (7%) | called by muse, mutect2
- PXN | c.831+1946G>A | Intron (SNP) | VAF 10/66 reads (15%) | called by mutect2, varscan2
- RAB35 | c.*1564G>A | 3'UTR (SNP) | VAF 11/144 reads (8%) | called by muse, mutect2
- SLCO2B1 | c.*948C>A | 3'UTR (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- SOWAHA | c.*901T>A | 3'UTR (SNP) | VAF 44/85 reads (52%) | called by muse, mutect2, varscan2
- TBC1D30 | c.*1054C>T | 3'UTR (SNP) | VAF 21/369 reads (6%) | catalogued as rs1019745958; called by muse, mutect2
- TGFBR1 | c.*2719G>A | 3'UTR (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- TTC6 | c.1201-4123G>A | Intron (SNP) | VAF 44/147 reads (30%) | called by muse, mutect2, varscan2
